Somatic mutation profile of cancer-model specimen HCM-CSHL-0655-C50-85N (3D Organoid, passage 4; aliquot HCM-CSHL-0655-C50-85N-01D-A82I-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0655-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 83.4 years (30,468 days).
Specimen HCM-CSHL-0655-C50-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90167c8c-3f88-4067-8807-a8c22dfd83c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0655-C50-10A (Blood Derived Normal), aliquot HCM-CSHL-0655-C50-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41e3d34e-801c-48be-962b-f6dbc834d755

The open-access MAF lists 40 somatic variants for this specimen: 31 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 21, Silent 9, Nonsense Mutation 4, Nonstop Mutation 2, Frame Shift Del 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.5039_5041del p.S1680del | In Frame Del (DEL) | VAF 239/527 reads (45%) | hotspot (GDC flag); catalogued as rs587783502; called by pindel, varscan2
- NSD1 | c.4411C>T p.R1471* | Nonsense Mutation (SNP) | VAF 20/252 reads (8%) | catalogued as rs570278338, CM030071, CM032972, COSV61786705; ClinVar: pathogenic; called by muse, mutect2
- APC | c.4381G>T p.E1461* | Nonsense Mutation (SNP) | VAF 163/364 reads (45%) | catalogued as COSV57325137, COSV99969827; called by muse, mutect2, varscan2
- CAMSAP1 | c.4555G>A p.A1519T | Missense Mutation (SNP) | VAF 181/380 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1319552847; called by muse, mutect2, varscan2
- CTNNB1 | c.1981C>G p.R661G | Missense Mutation (SNP) | VAF 145/307 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV62725225; called by muse, mutect2, varscan2
- MSH4 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 163/361 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV99592875; called by muse, mutect2, varscan2
- MYH2 | c.5513G>A p.R1838H | Missense Mutation (SNP) | VAF 66/287 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as rs117081954, COSV99819555; called by muse, mutect2, varscan2
- NOTCH1 | c.7425del p.V2476* | Frame Shift Del (DEL) | VAF 329/820 reads (40%) | catalogued as COSV53027102; called by mutect2, pindel, varscan2
- NOTCH1 | c.5162T>G p.V1721G | Missense Mutation (SNP) | VAF 163/355 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53030576, COSV53089655; called by muse, mutect2, varscan2
- PALD1 | c.2186C>T p.A729V | Missense Mutation (SNP) | VAF 202/427 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as rs192719429, COSV54978854; called by muse, mutect2, varscan2
- PDZD4 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 280/599 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1276121718, COSV99381067; called by muse, mutect2, varscan2
- PTPRS | c.1363G>A p.G455S | Missense Mutation (SNP) | VAF 289/617 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779471197; called by muse, mutect2, varscan2
- SEPTIN9 | c.1475G>A p.R492Q (on ENST00000427177 / NM_001113491.2; = p.R474Q on NM_006640.4) | Missense Mutation (SNP) | VAF 113/243 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as COSV100217443, COSV61203615; called by muse, mutect2, varscan2
- TEX13C | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 213/421 reads (51%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.996); catalogued as rs1006905046; called by muse, mutect2, varscan2
- TLE2 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 174/350 reads (50%) | catalogued as rs762086859; called by muse, mutect2, varscan2
- ZBTB33 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 16/390 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58533151; called by muse, mutect2
- ATF6B | c.1585A>G p.K529E | Missense Mutation (SNP) | VAF 285/536 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CEP170 | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 88/222 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- COL4A6 | c.3014G>A p.G1005D | Missense Mutation (SNP) | VAF 273/620 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EHF | c.695del p.R232Hfs*9 | Frame Shift Del (DEL) | VAF 171/408 reads (42%) | called by mutect2, pindel, varscan2
- FAM32A | c.338A>G p.*113Wext*54 | Nonstop Mutation (SNP) | VAF 128/245 reads (52%) | called by muse, mutect2, varscan2
- GK | c.1474C>T p.R492W (on ENST00000427190 / NM_001205019.2; = p.R486W on NM_000167.6) | Missense Mutation (SNP) | VAF 220/419 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KDM6A | c.988C>T p.Q330* | Nonsense Mutation (SNP) | VAF 119/275 reads (43%) | called by muse, mutect2, varscan2
- MARCHF11 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 115/229 reads (50%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLN | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 10/276 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.79); called by muse, mutect2
- PLPP3 | c.575+1G>A p.X192_splice | Splice Site (SNP) | VAF 87/175 reads (50%) | called by muse, mutect2, varscan2
- RAD17 | c.2044T>C p.*682Qext*? (on ENST00000380774 / NM_133339.2; = p.*671Qext*5 on NM_002873.1) | Nonstop Mutation (SNP) | VAF 123/223 reads (55%) | called by muse, mutect2, varscan2
- REST | c.1096T>G p.C366G | Missense Mutation (SNP) | VAF 154/313 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RUNX2 | c.983G>A p.G328E | Missense Mutation (SNP) | VAF 211/434 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- SIK2 | c.1747G>A p.G583S | Missense Mutation (SNP) | VAF 158/328 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF592 | c.1100G>A p.S367N | Missense Mutation (SNP) | VAF 213/446 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- FFAR2 | c.429C>T p.I143= | Silent (SNP) | VAF 171/348 reads (49%) | catalogued as COSV55832262; called by muse, mutect2, varscan2
- KIF5C | c.1989G>A p.S663= | Silent (SNP) | VAF 124/290 reads (43%) | catalogued as rs778459634; called by muse, varscan2
- PPP1R13B | c.3243G>A p.R1081= | Silent (SNP) | VAF 176/336 reads (52%) | called by muse, mutect2, varscan2
- REPS2 | c.1374A>G p.R458= | Silent (SNP) | VAF 127/313 reads (41%) | called by muse, mutect2, varscan2
- TFDP3 | c.129G>A p.P43= | Silent (SNP) | VAF 287/560 reads (51%) | catalogued as rs1323214571; called by muse, mutect2, varscan2
- TRMT10C | c.180G>A p.E60= | Silent (SNP) | VAF 102/282 reads (36%) | called by muse, mutect2, varscan2
- WFDC1 | c.252G>A p.Q84= | Silent (SNP) | VAF 223/468 reads (48%) | called by muse, mutect2, varscan2
- ZNF474 | c.855G>T p.V285= | Silent (SNP) | VAF 199/466 reads (43%) | called by muse, mutect2
- ZNF835 | c.615C>T p.R205= | Silent (SNP) | VAF 51/541 reads (9%) | catalogued as COSV101606257; called by muse, mutect2
